MMRF case MMRF_1016 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/742528e7-e938-4fa9-a3b2-ab641feb714c

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 692 days (1.9 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.2 years (20,534 days); ISS stage: I; Days to last known disease status: 692 days (1.9 years); Days to last follow up: 692 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 43 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 113 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 158 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 535 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 673 days (1.8 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 458 days (1.3 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 547 days (1.5 years); Days to treatment end: 673 days (1.8 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 692.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 2.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.598 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.35 mg/dL; Immunoglobulin G 29.5 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 1.26 g/L; Beta 2 Microglobulin 2.92 µg/mL; Lactate Dehydrogenase 3.82 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 8.6 g/dL; Glucose 4.29 mmol/L; C-Reactive Protein 0.17 mg/dL.
- Day 103 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.913 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.42 mg/dL; Immunoglobulin G 6.18 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 1.52 g/L; Hemoglobin 8.93 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.07 mmol/L.
- Day 184 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.594 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.937 mg/dL; Immunoglobulin G 5.97 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 1.63 g/L; Beta 2 Microglobulin 1.65 µg/mL; Lactate Dehydrogenase 3.32 µkat/L; Hemoglobin 9.42 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 254 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.861 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 6.63 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 2.02 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 357 (ECOG 0): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.13 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 1.6 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 4.51 mmol/L.
- Day 455 (ECOG 0): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.831 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.16 mg/dL; Immunoglobulin G 6.11 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 1.68 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.4 g/dL; Glucose 7.87 mmol/L.
- Day 518: M Protein 0.32 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.647 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.68 mg/dL; Immunoglobulin G 5.81 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 1.56 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 4.4 mmol/L.
- Day 647 (ECOG 0): M Protein 0.61 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.085 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.5 mg/dL; Immunoglobulin G 7.2 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 3.68 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 118 ×10⁹/L; Creatinine 99.9 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day 1: Weight: 105 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1016_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1016_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
